Surgical pathology report (de-identified scan), TCGA case TCGA-T1-A6J8, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site St. Joseph's Hospital Arizona, specimen TCGA-T1-A6J8-01A (Primary Tumor).

Pathology Report

Date of Surgery:

Diagnosis:

Hepatocellular carcinoma, trabecular and acinar patterns, grade II (moderately differentiated) right liver

Lymph-vascular and perineural invasion not identified.

Microscopic Description:

The hepatic neoplasm shows scattered foci of strongly reactive cells utilizing hepatocyte specific antigen. CD10 is not significantly reactive, nor is AFP. The native liver shows no increase in fibrosis utilizing a trichrome stain. No reactive globules are noted utilizing PAS with and without diastase. A Prussian blue stain shows isolated, minimal granular hepatocyte iron.

ICD0-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
Op 6/28/13

Source: NCI Genomic Data Commons file d3905041-3174-42ac-bfc8-b72d4d69110a (TCGA-T1-A6J8.CEAA3A97-FE48-4408-9DCA-21D924287CAC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).